Somatic mutation profile of cancer-model specimen HCM-CSHL-1264-C25-85A (3D Organoid; aliquot HCM-CSHL-1264-C25-85A-01D-A882-36), derived from the primary tumor of HCMI case HCM-CSHL-1264-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.5 years (28,315 days).
Specimen HCM-CSHL-1264-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3cf8342-75cc-4db8-bb44-7b5fb26c649f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1264-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-1264-C25-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fef9b61d-2860-4782-b77f-009190a67029

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Intron 1, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 118/270 reads (44%) | catalogued as rs1555075658; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 143/299 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 286/482 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BMP10 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 202/528 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs767045695, COSV54897254; called by muse, mutect2, varscan2
- BSN | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 271/511 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773730740, COSV56521075; called by muse, mutect2, varscan2
- CARMIL2 | c.2305T>C p.S769P | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1038850771; called by muse, varscan2
- CDH7 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59886229; called by muse, mutect2, varscan2
- CSF1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs769264432; called by muse, mutect2, varscan2
- DSCAM | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 250/522 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs374471813; called by muse, mutect2, varscan2
- ESR1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 296/529 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776270356, COSV52789413; called by muse, mutect2, varscan2
- EVC | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 226/428 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs769319527; called by muse, mutect2, varscan2
- HDAC1 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV65191080; called by muse, mutect2
- HTR7 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 231/518 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs141895642; called by muse, mutect2, varscan2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 215/424 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- LAMC3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 54/1108 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs778884818, COSV63088242; called by muse, mutect2
- NUP210 | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 257/518 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147955019; called by muse, mutect2, varscan2
- OBSCN | c.22378G>A p.D7460N | Missense Mutation (SNP) | VAF 145/334 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV63478466; called by muse, mutect2, varscan2
- RBMXL3 | c.3092C>T p.T1031M | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782693566; called by muse, mutect2, varscan2
- RUNX1 | c.410T>A p.V137D (on ENST00000344691 / NM_001001890.3; = p.V164D on NM_001754.5) | Missense Mutation (SNP) | VAF 153/275 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55881157; called by muse, mutect2, varscan2
- SHMT2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 184/418 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs112251410; called by muse, mutect2, varscan2
- SLC27A1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465598398; called by muse, mutect2, varscan2
- TBC1D3F | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1185448665; called by muse, mutect2, varscan2
- TG | c.7877C>T p.A2626V | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1321536850, COSV99603793; called by muse, mutect2, varscan2
- TXLNB | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781557596, COSV64445974; called by muse, mutect2, varscan2
- XIRP2 | c.6995C>A p.T2332N (on ENST00000628543; = p.T2507N on NM_152381.6) | Missense Mutation (SNP) | VAF 157/378 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs756049993; called by muse, mutect2, varscan2
- ADCY4 | c.2552C>A p.A851D | Missense Mutation (SNP) | VAF 246/477 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGAP31 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 222/451 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCL9 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 205/428 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CERS5 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 233/477 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CXCL12 | c.110G>C p.S37T | Missense Mutation (SNP) | VAF 192/366 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GGN | c.1848C>G p.S616R | Missense Mutation (SNP) | VAF 167/383 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPCPD1 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 208/448 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MASP2 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 33/425 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- MUC6 | c.596dup p.F200Vfs*43 | Frame Shift Ins (INS) | VAF 222/540 reads (41%) | called by mutect2, pindel, varscan2
- NIPBL | c.7240C>T p.L2414F | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM10 | c.2012del p.N671Ifs*33 | Frame Shift Del (DEL) | VAF 266/368 reads (72%) | called by mutect2, pindel, varscan2
- SERTAD2 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 233/495 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- SMPD4 | c.1584C>G p.F528L (on ENST00000409031 / NM_017951.4; = p.F499L on NM_017751.4) | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCC2 | c.4185C>T p.L1395= | Silent (SNP) | VAF 123/349 reads (35%) | catalogued as rs778709751; called by muse, mutect2, varscan2
- AFAP1L2 | c.1062C>T p.L354= | Silent (SNP) | VAF 28/389 reads (7%) | catalogued as rs747164722; called by muse, mutect2
- AHNAK | c.4212G>A p.V1404= | Silent (SNP) | VAF 183/404 reads (45%) | catalogued as COSV57202354; called by muse, mutect2, varscan2
- C10orf71 | c.3945C>T p.S1315= | Silent (SNP) | VAF 27/615 reads (4%) | called by muse, mutect2
- GPR45 | c.201G>A p.S67= | Silent (SNP) | VAF 285/560 reads (51%) | catalogued as rs779954345, COSV51522604; called by muse, mutect2, varscan2
- KCNMA1 | c.3021C>T p.N1007= (on ENST00000286628 / NM_001161352.2; = p.N949= on NM_002247.4) | Silent (SNP) | VAF 19/245 reads (8%) | catalogued as rs369363787; ClinVar: likely benign; called by muse, mutect2
- KLHL26 | c.541C>A p.R181= | Silent (SNP) | VAF 44/660 reads (7%) | catalogued as COSV56318597; called by muse, mutect2
- LACTBL1 | c.954C>T p.D318= (on ENST00000618559; = p.D363= on NM_001289974.2) | Silent (SNP) | VAF 349/713 reads (49%) | called by muse, mutect2, varscan2
- LRRN1 | c.252C>T p.I84= | Silent (SNP) | VAF 160/322 reads (50%) | catalogued as rs267599791; called by muse, mutect2, varscan2
- OSBP2 | c.900C>T p.S300= | Silent (SNP) | VAF 163/489 reads (33%) | catalogued as rs370995568; called by muse, mutect2, varscan2
- OTOF | c.2205C>T p.A735= | Silent (SNP) | VAF 176/345 reads (51%) | catalogued as rs761710670; called by muse, mutect2, varscan2
- QPCTL | c.528C>T p.P176= | Silent (SNP) | VAF 58/679 reads (9%) | catalogued as rs1304616961; called by muse, mutect2
- RP1L1 | c.1605G>A p.S535= | Silent (SNP) | VAF 307/625 reads (49%) | catalogued as rs200772091; ClinVar: benign; called by muse, mutect2, varscan2
- COL6A5 | c.-121G>A | 5'UTR (SNP) | VAF 56/580 reads (10%) | called by muse, mutect2
- JMJD4 | c.692+82del | Intron (DEL) | VAF 308/742 reads (42%) | called by mutect2, pindel, varscan2
